Surgical pathology report (de-identified scan), TCGA case TCGA-XK-AAJ3, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Mayo Clinic Arizona, specimen TCGA-XK-AAJ3-01A (Primary Tumor).

[page 1 of 3]
ICD-O 3
Adenocarcinoma NOS 840/3
Site: Prostate NOS C61.9
9/23/25/14

Surgical Pathology Report

ADDENDUM PRESENT

Patient Name: [REDACTED]
Clinic Number: [REDACTED]
Date of Birth: [REDACTED] (Age: [REDACTED] Gender: M)
Requested By: [REDACTED]

Accession #: [REDACTED]
Procedure Date: [REDACTED]
Received Date: [REDACTED]
Account #: [REDACTED]
Report Signed: [REDACTED]

Final Diagnosis:

Procedure: Radical prostatectomy with right and left pelvic lymph node dissections.

Histologic type: Adenocarcinoma of the prostate, acinar type.

Histologic grade:

Primary pattern: 4 Secondary pattern: 4

Total Gleason Score: 4+4=8.

Tumor quantitation: Tumor can be seen in both the right and left prostate extending from apex to base on the right side, involving the left apex and left mid prostate, and sparing the left base. Largest diameter of carcinoma on the right is 14 mm in diameter, and on the left is 10 mm in diameter in the right mid prostate and left apex, respectively.

Extraprostatic extension: There is focal extraprostatic extension in the posterior right mid prostate, in an area less than 1 mm in length.

Margins: The distal urethral, proximal urethral, apical, bladder neck, and external capsular margins are all negative for carcinoma.

Lymph-vascular invasion: Absent.

Perineural invasion: There is perineural invasion within the body of the carcinoma and in carcinoma involving the capsular condensation in the right posterior prostate.

Seminal vesicle invasion: Absent.

Treatment effect on carcinoma: Not applicable.

Lymph nodes: Six pelvic lymph nodes total, not designated as to laterality, all negative for carcinoma.

Additional pathologic findings: High-grade prostatic intraepithelial neoplasia.

Ancillary studies: DNA ploidy ordered on block A8 (to be reported in an ADDENDUM).

Pathologic staging: pT3a, pN0

Biorepository sample (if applicable): Yes, contains carcinoma.

Block(s) containing malignancy suitable for additional testing: A3, A4, A7, A8, A10, A12, A14, A16.

Slide A12 showing extraprostatic extension was reviewed with [REDACTED], who agrees in this interpretation.

Interpreted by:

Report electronically signed out by

Transcribed by:

ADDENDA:

[page 2 of 3]
Paraffin-embedded tissue (Block A8) was forwarded to report / interpreted by

for DNA Ploidy by

The

follows:

Source: Prostate, radical prostatectomy, block A8

Results:

The cancer cells are DNA near diploid; DNA index = 1.15.

DNA ploidy test results have been validated by our laboratory for formalin-fixed, paraffin embedded tissue sections. Analysis was performed using the instrument , which determined DNA ploidy status by comparing the DNA content of tumor cells and control cells (selected by operator). This test was developed and its performance characteristics determined by ; this test has not been cleared or approved by the U.S. Food and Drug Administration.

Proliferation index (MIB-1) = 3.81%.

Ki-67 Antigen immunohistochemical test results have been validated by our laboratory for paraffin embedded tissue sections fixed in formalin. Testing is performed using the MIB-1 reagent and a polymer-based detection system. All controls show appropriate reactivity. Image collection and analysis is performed using the instrument, . The renders the percentage of positive staining tumor nuclei (tumor selected by operator). This test was developed and its performance characteristics determined by ; This test has not been cleared or approved by the U.S. Food and Drug Administration.

Transcribed by

Signed by

Clinical Information:

Prostate cancer.

Specimen(s):

A: Prostate with bilateral lymph nodes

Gross Description:

Performed by Pathologist's Assistant

A1A2A3A4A5A6A7A8A9A10A11A12A13A14A15A16A17A18A19A20

Received fresh labeled and "prostate and bilateral pelvic lymph nodes."

Procedure: Radical prostatectomy with right and left lymph node dissection.

Prostate size: Weight: 45 grams; Dimensions: 4.5 x 4 x 3.8 cm; Seminal vesicles: 2.5 x 1.6 x 1 cm.

Gross notes: Grossly evident tumor: Yes, 1.7 x 1.5 x 1.5 cm in the right apex-mid lobe.

Symmetry: Symmetrical.

Gross nodular hyperplasia: Moderate.

Gross capsular bulge/defect: Slight bulge in the right mid posterior capsule.

Inking: left-black, right-blue

Biorepository sample collected: Yes, see block key #17.

Lymph nodes: Multiple pieces of adipose tissue designated bilateral pelvic lymph nodes are submitted aggregating to 7 x 4 x 2 cm. Within the adipose tissue are several fatty lymph nodes.

[page 3 of 3]
Block key for specimen :

- 1) proximal urethral margin
- 2) distal urethral margin
- 3) left apical margin
- 4) right apical margin
- 5) left bladder neck margin
- 6) right bladder neck margin
- 7) left apical prostate
- 8) right apical prostate
- 9) left mid prostate
- 10) right mid prostate
- 11) left mid prostate
- 12) right mid prostate
- 13) left base of prostate
- 14) right base of prostate
- 15) left seminal vesicle
- 16) right seminal vesicle

Additional sections:

- 17) mirror image of tissue corresponding to research
- 18) one fatty pelvic lymph node
- 19) three possible fatty lymph nodes.
- 20) two possible fatty lymph nodes

Support for the diagnosis in this case may have included the use of immunohistochemistry tests that were developed and whose performance characteristics were determined by
They have not been cleared or approved by the U. S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is
not necessary. These tests should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as
qualified to perform high complexity clinical laboratory testing

Source: NCI Genomic Data Commons file c8cbce16-70e5-4b1b-bbae-d368601884b1 (TCGA-XK-AAJ3.6DAD48EB-0C26-4417-A2C1-57332165EEF2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).